TCGA case TCGA-60-2696 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bff77f70-973a-4b49-8fd9-4a767f5df2c0

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Dead; Days to death: 109 days.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.6 years (27,991 days); Year of diagnosis: 2009; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Residual disease: RX; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the thymus (histology not recorded by GDC).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: -417 days (-1.1 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Prior primary; AJCC staging edition: 4th; AJCC pathologic T: T1b; AJCC pathologic N: N0.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Treatment anatomic sites: Locoregional Site.

Follow-up (2 entries)
- Karnofsky performance status: 0.
- Follow-up contact recording only the day: day 109.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1955; Tobacco smoking quit year: 1985.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-60-2696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-60-2696-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 35; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-60-2696-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-60-2696-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-60-2696-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Days to last known alive: 108; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Follow-up form: New tumor event diagnosis indicator: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -4289.
- Other malignancy form 1, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form 1, Drug treatment, Administered drug: Pharmaceutical therapy drug name: tomoxifen.
- Other malignancy form 1, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: Yes.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -8440.
- Other malignancy form 2, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: carboplatin, paclitaxel.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy breast cancer treated w/ tamoxifen and radiation and tymus cancer treated w/ cancerrboplatin and Paclitaxel.
- Prior malignancy: Subject has Hx of prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 109 days; disease-specific survival: event status not recorded, 109 days; progression-free interval: no event (censored), 109 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-60-2696-01): tumor purity 0.42, ploidy 1.72, whole-genome doublings 0 (call status: snp_call).
